Gene-level copy-number profile of tumor specimen TCGA-DD-AAD1-01A from TCGA case TCGA-DD-AAD1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 51.5 years (18,794 days).
Specimen TCGA-DD-AAD1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.dd3627f2-265c-43fd-8933-378d0ba102f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAD1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dee9e866-70ba-4113-9b5b-1ff5818a7b33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,631; copy number 2: 45,872; copy number 3: 5,723; copy number 4: 66; copy number 5: 87; copy number 6: 926; copy number 8: 515.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAD1-01A-11D-A40Q-01): tumor purity 0.44, ploidy 2.19, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,528 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,549,089–50,860,062, 75 genes, copy number 5 (broad region; genes not listed).
- chr8:52,534,037–145,066,685, 1,441 genes, copy number 6–8 (broad region; genes not listed).
- chr11:62,337,448–62,426,724, 5 genes, copy number 5 (within-gene range 3–5): ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2.
- chr20:17,887,363–18,059,188, 7 genes, copy number 5 (within-gene range 2–5): AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3.

Autosomal genes at a single copy (total copy number 1): 6,631. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
